Gene-level copy-number profile of tumor specimen TCGA-CH-5761-01A from TCGA case TCGA-CH-5761, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 61.4 years (22,433 days).
Specimen TCGA-CH-5761-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.111acb48-3962-4e19-88ce-ddbed021777e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CH-5761-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1ef208dd-8867-4cea-8af7-662dc61d5a2e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 2: 12,840; copy number 3: 2,730; copy number 4: 37,607; copy number 5: 190; copy number 6: 4,995; copy number 7: 199; copy number 8: 277; copy number 9: 247; copy number 10: 264; copy number 11: 264; copy number 12: 42; copy number 14: 14; copy number 15: 5; copy number 16: 15; copy number 20: 91; copy number 22: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CH-5761-01A-11D-1574-01): tumor purity 0.7, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:24,912,165–25,688,786, 17 genes: AF106564.1, NEFM, NEFL, MIR6841, AC107373.2, AC107373.1, AC107373.3, AC073581.1, AC041005.1, DOCK5, AC091185.2, MIR6876, GNRH1, AC091185.1, KCTD9, CDCA2, AC009623.1.
- chr21:46,635,595–46,665,124, 2 genes: PRMT2, DSTNP1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 960 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:28,213,359–40,312,905, 194 genes, copy number 9 (broad region; genes not listed).
- chr10:52,765,380–55,627,942, 18 genes, copy number 9–15: MBL2, Y_RNA, AC073174.1, LINC02672, SNRPEP8, AC036101.1, RNA5SP318, AL365496.1, PCDH15, RNU6-687P, AL353784.1, NEFMP1, MIR548F1, AC051618.1, AC016822.1, AL355314.1, AL355314.2, MTRNR2L5.
- chr10:59,650,761–74,709,963, 276 genes, copy number 9–20 (within-gene range 8–20) (broad region; genes not listed).
- chr10:76,869,601–77,638,369, 1 gene, copy number 11 (within-gene range 8–11): KCNMA1.
- chr10:77,147,652–89,652,144, 239 genes, copy number 11 (broad region; genes not listed).
- chr10:89,915,489–89,979,070, 2 genes, copy number 11 (within-gene range 2–11): LINC01375, SNRPD2P1.
- chr12:79,690,144–80,068,757, 9 genes, copy number 9 (within-gene range 4–9): AC073569.2, PPP1R12A, AC073569.3, AC073569.1, RNA5SP363, PPP1R12A-AS1, SNRPGP20, RPL7P38, RNU7-106P.
- chr12:121,874,193–122,634,673, 28 genes, copy number 10: AC069503.3, AC069503.5, PSMD9, AC069503.2, Metazoa_SRP, RNU7-170P, CFAP251, AC069503.1, BCL7A, AC156455.1, MLXIP, LRRC43, IL31, B3GNT4, AC048338.2, DIABLO, AC048338.1, VPS33A, CLIP1, RPL21P1, CLIP1-AS1, ZCCHC8, AC127002.1, AC127002.2, RSRC2, KNTC1, AC026333.1, AC026333.4.
- chr12:125,065,434–127,826,286, 60 genes, copy number 12–22 (within-gene range 6–22): AACS, AC122688.3, AC122688.2, AC122688.5, AC122688.4, TMEM132B, AC093028.1, AC005252.2, AC005252.4, AC005252.3, AC005252.1, LINC00939, LINC02826, LINC02359, AC005858.2, AC005858.3, AC005858.1, AC005888.1, AC007368.1, LINC02825, LINC02347, FAM32EP, AC006065.1, NDUFA5P6, AC006065.4, AC006065.2, AC006065.3, AC006065.5, AC006065.6, LINC02824, LINC00943, LINC00944, AC078878.1, LINC02372, AC078878.2, HSPE1P20, LINC02405, AC079949.3, AC079949.1, AC079949.5, AC079949.2, AC079949.6, LINC02376, AC073913.1, RNU1-104P, LINC02375, AC073913.2, AC048347.1, AC068787.4, AC068787.1, AC068787.3, AC068787.2, AC068787.5, AC025252.1, Y_RNA, AC025252.2, LINC02411, AC025160.1, AC087894.3, AC087894.2.
- chr20:43,189,998–46,432,985, 133 genes, copy number 10–20 (within-gene range 4–20) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
